CCDI case PBBVIA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Other and unspecified urinary organs.
https://portal.gdc.cancer.gov/cases/0ba74b11-c905-4bc1-9cf6-f03807e820d8

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Urinary system, NOS; Age at diagnosis: 14.5 years (5,301 days).

Biospecimens (4 samples)
- Samples 0DI3J1, 0DI3NI (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DI3JI: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DI6L2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
